CCDI case PBBRZX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5096b38e-f58b-4fd4-801a-52c850c93d5a

Demographics
Sex at birth: female; Race: black or african american; Vital status: Dead.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,439 days).

Biospecimens (3 samples)
- Sample 0DFDAP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFDB1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFDC9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
